FM case AD10123 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/9b701375-1168-4222-ac5a-a32b4a7cebb0

Female, 32.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the cervix uteri; primary biopsied or resected from the cervix uteri. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
